Gene-level copy-number profile of specimen HCM-BROD-0104-C71-85B from HCMI case HCM-BROD-0104-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.0 years (23,020 days).
Specimen HCM-BROD-0104-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9cd4b7ca-c81a-4936-8060-d988f655d486.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0104-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/d9582106-880d-4f01-9854-423e64fdaa6e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 29; copy number 2: 2,224; copy number 3: 1,455; copy number 4: 47,761; copy number 5: 180; copy number 6: 6,545; copy number 9: 25; copy number 10: 145; copy number 22: 24.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 194 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,230,030–12,841,357, 16 genes, copy number 10: VPS13D, SNORA59A, LINC02766, DHRS3, RNU6ATAC18P, MIR6730, AC254633.1, AADACL4, AC244670.1, AADACL3, C1orf158, PRAMEF12, PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P.
- chr1:13,049,476–19,329,300, 178 genes, copy number 9–22 (within-gene range 4–22) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 29. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
